Surgical pathology report (de-identified scan), TCGA case TCGA-A7-A5ZW, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Christiana Healthcare, specimen TCGA-A7-A5ZW-01A (Primary Tumor).

[page 1 of 2]
ICD-O-3

Carcinoma, duct in situ

Site: R Breast NOS
8504/3
C50.9

JW 4/12/13

Final Surgical Pathology Report

Procedure:

Diagnosis

A. Breast, right, lumpectomy:

Invasive ductal carcinoma, grade 2; 1.7 cm (pT1c)
Ductal carcinoma in situ, cribriform type, nuclear grade 2
Resection margins negative for invasive and in situ carcinoma
Unremarkable skin

B. Right axillary sentinel lymph node, excisional biopsy: Metastatic ductal carcinoma, 7 mm size with extranodal extension (snpN1a)

Microscopic Description:

Microscopic examination performed.

A. Microscopic examination of the right breast lumpectomy specimen is summarized in the template below:

Invasive Carcinoma:

Histologic type: Invasive ductal carcinoma

Histologic grade: 2

Overall grade:

Architectural score: 2

Nuclear score: 2

Mitotic score: 2

Greatest dimension (pT): 1.7 CM (pT1c)

Specimen margins: Negative for carcinoma. Closest margin is superior where tumor is 5 mm from the margin.

Vessel invasion: Not identified

Calcification: Present

Ductal carcinoma in situ:

Histologic pattern: -Cribriform

Nuclear grade: 2

Central Necrosis: Absent

% DCIS of total tumor (if mixed): Approximately 10%

Extensive intraductal component (present/absent): Absent

Specimen margins: Negative for DCIS

Calcification: Focally present

Description of non-tumorous breast: Fibrosis, apocrine metaplasia, microcysts and ordinary ductal hyperplasia and adenosis.

Comments: Core biopsy site changes are present. The tumor areas of slightly higher grade than the original core biopsy interpretation due to more mitotic activity. The skin is histologically unremarkable with no extension of tumor into the skin ellipse.

Prognostic markers: Performed on the prior core biopsy

B. Microscopic examination of the sentinel node involve the evaluation of 3 H&E-stained sections of each of the 3 tissue blocks. Metastatic ductal carcinoma is identified in blocks 1 and 2 and extranodal tumor is identified in block 1. The size of the tumor is 7 mm ()

[page 2 of 2]
Specimen

- A. Right breast segments
- B. Right sentinel lymph node axilla (hot/blue 812)

Clinical Information

Breast cancer

Gross Description

A. Received fresh and subsequently fixed in formalin labeled "right breast segment" is a 9.3 x 8.7 x 4.3 cm yellow lobular fatty tissue fragment showing gross evidence of blue ink staining. The specimen is received in a transpect container and is partially covered with a 5.7 x 1.3 cm brown-tan wrinkled skin ellipse. The specimen has a double suture designating anterior and a single suture designating lateral. The specimen is inked as follows: The margins are inked as follows based upon the orienting sutures: superior - orange; anterior - blue; posterior - black; inferior - green. The specimen is serially sectioned from medial to lateral. The specimen shows a yellow white, fibrofatty cut surface with a 1.7 x 1.5 x 1.5 cm ill circumscribed white tan firm lesion which comes within 0.5 cm of the superior margin, 1.5 cm of the inferior margin, within 2 cm of the skin, greater than 5 cm of the posterior margin and greater than 2.5 cm of the medial and lateral margins. The lesion is stellate and shows white rice-like pellets, grossly consistent with previous biopsy site. No additional gross lesions are identified. The specimen is received in pathology at and fixed in formalin at . Representative sections of

the specimen are submitted as follows: 1 - representative medial margin, 2 - representative lateral margin, 3 - representative section of the deep/ posterior margin, 4 - 10 - representative sections of tumor to closest margin and skin. RS 10.

B. Received fresh and subsequently fixed in formalin labeled "right sentinel node" is a 2.4 x 1.5 x 1.0 cm blue stained pink yellow irregular rubbery tissue fragment. The specimen is trisected to show an irregular white firm central focus measuring 0.7 cm in greatest dimension. AS- 3.

Source: NCI Genomic Data Commons file e080558a-5aa9-46f1-8f5a-b3e7fb63b427 (TCGA-A7-A5ZW.A56585F9-9651-472B-BF53-C708A686EB7D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).